Somatic mutation profile of tumor specimen TCGA-AA-3867-01A (aliquot TCGA-AA-3867-01A-01W-0995-10) from TCGA case TCGA-AA-3867, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.0 years (27,028 days).
Specimen TCGA-AA-3867-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f56f9ee0-62c8-4466-8395-00abc9f61642.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3867-10A (Blood Derived Normal), aliquot TCGA-AA-3867-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/330aa41c-e856-4fff-b073-07d4d3297d18

The open-access MAF lists 107 somatic variants for this specimen: 82 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 22, Frame Shift Del 6, Nonsense Mutation 5, Intron 2, Frame Shift Ins 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 131/283 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 57/415 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as rs746482766, COSV100735845; called by muse, mutect2, varscan2
- ABCA12 | c.2869_2870insG p.I957Sfs*3 (on ENST00000272895 / NM_173076.3; = p.I639Sfs*3 on NM_015657.3) | Frame Shift Ins (INS) | VAF 113/552 reads (20%) | catalogued as COSV99792584; called by mutect2, pindel, varscan2
- ABCA5 | c.2684T>G p.L895R | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101201317; called by muse, varscan2
- ABT1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs782097640, COSV51293795; called by muse, mutect2, varscan2
- ADAMTS17 | c.2253G>T p.K751N | Missense Mutation (SNP) | VAF 134/333 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99172532; called by muse, mutect2, varscan2
- ADAMTSL1 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 160/689 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771200194, COSV52821802; called by muse, mutect2, varscan2
- AL645922.1 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV54962978; called by muse, mutect2, varscan2
- AMER2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV63437031; called by muse, mutect2, varscan2
- ARID1A | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 28/128 reads (22%) | catalogued as COSV61389265; called by muse, mutect2, varscan2
- ARID2 | c.5126G>A p.G1709E | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV100537206; called by muse, mutect2, varscan2
- ARNTL | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 297/821 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62989262; called by muse, mutect2, varscan2
- BCLAF1 | c.2718A>C p.E906D | Missense Mutation (SNP) | VAF 168/502 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99219931; called by muse, mutect2, varscan2
- C20orf141 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181014957, COSV100730151, COSV63028787; called by muse, mutect2, varscan2
- CARD18 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 179/804 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as COSV73233164; called by muse, mutect2, varscan2
- CARD18 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 177/802 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV101596042; called by muse, mutect2, varscan2
- CARF | c.897dup p.V300Sfs*3 | Frame Shift Ins (INS) | VAF 54/279 reads (19%) | catalogued as rs751635415; called by mutect2, varscan2
- CNKSR2 | c.2105G>A p.S702N | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as COSV99670218; called by muse, mutect2
- COL4A1 | c.2354G>A p.G785E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65424361; called by muse, varscan2
- CPA1 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99163391; called by muse, mutect2, varscan2
- CSMD1 | c.9499C>T p.L3167F (on ENST00000520002; = p.L3166F on NM_033225.6) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as COSV59355038; called by muse, mutect2, varscan2
- CSMD2 | c.8018T>A p.L2673Q | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.952); catalogued as COSV53944790; called by muse, mutect2, varscan2
- CYRIA | c.637A>C p.T213P | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as COSV62864922; called by muse, mutect2, varscan2
- DAB2IP | c.593G>A p.R198Q (on ENST00000408936; = p.R170Q on NM_032552.3) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.968); catalogued as rs368193656; called by muse, mutect2, varscan2
- DSCAM | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 331/480 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs1569071469, COSV68021488; called by muse, mutect2, varscan2
- EPAS1 | c.2291A>T p.K764M | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99763779; called by muse, mutect2, varscan2
- FAT2 | c.9033T>G p.C3011W | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99944440; called by muse, mutect2, varscan2
- FER | c.869T>A p.L290H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55308782; called by muse, mutect2, varscan2
- GABRA2 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.041); catalogued as COSV62915075; called by muse, mutect2, varscan2
- GML | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 81/587 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV99638681; called by muse, mutect2, varscan2
- GRIA4 | c.563A>T p.N188I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV56920042, COSV99235343; called by muse, mutect2, varscan2
- GRIK3 | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 98/379 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770933463, COSV100902469; called by muse, mutect2, varscan2
- HPSE2 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as rs369345201, COSV100984618; called by muse, mutect2, varscan2
- HTR2C | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 389/561 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194076654, COSV52220873; called by muse, mutect2, varscan2
- IP6K3 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745744083, COSV53392265; called by muse, mutect2, varscan2
- KCNH5 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763607260, COSV100524909; called by muse, varscan2
- KIF21A | c.3967A>C p.I1323L (on ENST00000361418 / NM_001378440.1; = p.I1310L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100735647, COSV100735770; called by muse, mutect2, varscan2
- LILRB4 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 269/1108 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs371595706; called by muse, mutect2, varscan2
- LTBP4 | c.2452T>G p.C818G (on ENST00000308370 / NM_001042544.1; = p.C781G on NM_003573.2) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52592411; called by muse, mutect2, varscan2
- LUC7L2 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.973); catalogued as rs754703629, COSV99693544; called by muse, mutect2, varscan2
- MED31 | c.355T>A p.L119M | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.969); catalogued as COSV51514475; called by muse, mutect2, varscan2
- MIA2 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1405221877, COSV99696979; called by muse, mutect2, varscan2
- MNT | c.1600G>T p.G534C | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as COSV51514318; called by muse, mutect2, varscan2
- MRPL4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372085895, COSV53447560; called by muse, varscan2
- MTFR2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 246/586 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200368436, COSV63080535; called by muse, mutect2, varscan2
- MTOR | c.2366A>T p.D789V | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100816785; called by muse, mutect2, varscan2
- NCAPG2 | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs377006246; called by muse, mutect2, varscan2
- NPHS1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs751182197, COSV62289800; called by muse, mutect2, varscan2
- NRXN1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101280859; called by muse, mutect2, varscan2
- OR10C1 | c.224C>T p.T75M (on ENST00000622521; = p.T73M on NM_013941.3) | Missense Mutation (SNP) | VAF 158/405 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1252276618, COSV65822507; called by muse, mutect2, varscan2
- PBX2 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); catalogued as rs763303454; called by muse, mutect2
- PDZD2 | c.3008G>A p.R1003H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs753028675, COSV56865963, COSV99224254; called by muse, mutect2, varscan2
- PLEKHA4 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 168/619 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV99613478; called by muse, mutect2, varscan2
- PLXND1 | c.5039C>T p.T1680M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs569800532, COSV60709082; called by muse, mutect2, varscan2
- POPDC2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 15/484 reads (3%) | catalogued as COSV51739677, COSV51743126; called by muse, mutect2
- PRSS1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV61193878; called by muse, mutect2, varscan2
- PRSS35 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 83/362 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757842601, COSV63800328; called by muse, mutect2, varscan2
- PTCHD3 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs746518651, COSV71256401, COSV71256933; called by muse, mutect2, varscan2
- PTPRK | c.1522T>G p.F508V | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV100951724; called by muse, mutect2, varscan2
- RANBP3L | c.1377_1380del p.R459Sfs*12 | Frame Shift Del (DEL) | VAF 101/216 reads (47%) | catalogued as rs754638549; called by pindel, varscan2
- RASGRF1 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV101369796; called by muse, mutect2, varscan2
- SACS | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 245/427 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs561282342, COSV101207246, COSV101207486; called by muse, mutect2, varscan2
- SAMD12 | c.216A>T p.K72N | Missense Mutation (SNP) | VAF 60/658 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59058463; called by muse, mutect2
- SLC17A4 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100930698; called by muse, mutect2, varscan2
- SOST | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100059844; called by muse, mutect2, varscan2
- STX5 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 237/599 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1383465486, COSV53682475; called by muse, mutect2, varscan2
- SYNPO2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 57/171 reads (33%) | catalogued as COSV100206567; called by muse, mutect2, varscan2
- TMEM168 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100454848; called by muse, mutect2
- TOP1 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV63696870; called by muse, mutect2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 48/95 reads (51%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- TSFM | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV100103811, COSV55745065; called by muse, mutect2, varscan2
- TTN | c.92245G>T p.E30749* (on ENST00000591111; = p.E23325* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 42/296 reads (14%) | catalogued as COSV100635076; called by muse, mutect2, varscan2
- UGGT2 | c.3244A>T p.T1082S | Missense Mutation (SNP) | VAF 190/537 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV100948986; called by muse, mutect2, varscan2
- USP34 | c.8899G>A p.G2967R | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV101277303; called by muse, mutect2, varscan2
- VAV3 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 136/400 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV58394133; called by muse, mutect2, varscan2
- XIRP1 | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs754187803, COSV61137398; called by muse, mutect2, varscan2
- ZMYND15 | c.1931G>C p.S644T (on ENST00000433935 / NM_001136046.3; = p.S605T on NM_032265.2) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as COSV52645495; called by muse, mutect2, varscan2
- CARM1 | c.1355_1359del p.I452Sfs*12 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- H2AC8 | c.277del p.E93Sfs*2 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- KDM4A | c.2356_2358del p.Q786del | In Frame Del (DEL) | VAF 297/909 reads (33%) | called by mutect2, pindel, varscan2
- PNISR | c.1419del p.A474Qfs*20 | Frame Shift Del (DEL) | VAF 83/340 reads (24%) | called by mutect2, pindel, varscan2
- TICRR | c.1871_1874del p.G624Efs*3 | Frame Shift Del (DEL) | VAF 69/257 reads (27%) | called by mutect2, pindel, varscan2
- ACKR2 | c.600C>T p.G200= | Silent (SNP) | VAF 175/435 reads (40%) | catalogued as rs375376109; called by muse, mutect2, varscan2
- CD300LG | c.783C>T p.A261= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1410214718, COSV53226670; called by muse, mutect2, varscan2
- CHST11 | c.669C>T p.N223= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs781426215, COSV57990137; called by muse, mutect2, varscan2
- COL1A2 | c.2796C>T p.N932= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs757671800, COSV51954303, COSV51956506; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPXM1 | c.2061C>A p.V687= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- CXCR1 | c.45A>G p.L15= | Silent (SNP) | VAF 125/337 reads (37%) | catalogued as COSV55283290; called by muse, mutect2, varscan2
- ECT2L | c.2714G>A p.*905= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as COSV99239134; called by muse, mutect2
- EIF4G3 | c.1326G>A p.P442= | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as rs766510132, COSV51696155; called by muse, mutect2, varscan2
- ERBB4 | c.3748C>A p.R1250= | Silent (SNP) | VAF 121/354 reads (34%) | catalogued as COSV61500180, COSV61530008; called by muse, varscan2
- ERICH6 | c.912G>A p.L304= | Silent (SNP) | VAF 75/386 reads (19%) | catalogued as rs1418375266, COSV55803789; called by muse, mutect2, varscan2
- FAM111A | c.999G>A p.T333= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs755864654, COSV64656040; called by muse, mutect2, varscan2
- HPX | c.627C>T p.F209= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as rs1016472623, COSV56421040; called by muse, mutect2
- KIAA1210 | c.2721G>A p.Q907= | Silent (SNP) | VAF 154/205 reads (75%) | catalogued as COSV68180771; called by muse, mutect2, varscan2
- LRRC3B | c.309C>T p.I103= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs1358691804, COSV67521110; called by muse, mutect2, varscan2
- NAA35 | c.1488C>T p.N496= | Silent (SNP) | VAF 18/575 reads (3%) | catalogued as COSV100863473; called by muse, mutect2
- NCAM1 | c.840C>T p.N280= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as rs1293661395, COSV57520058; called by muse, mutect2, varscan2
- NR1H4 | c.378G>A p.A126= (on ENST00000551379 / NM_001206993.2; = p.A116= on NM_005123.4) | Silent (SNP) | VAF 118/224 reads (53%) | catalogued as rs767379406, COSV51849366, COSV51853756; called by muse, mutect2, varscan2
- PIKFYVE | c.3051C>T p.D1017= | Silent (SNP) | VAF 39/329 reads (12%) | catalogued as COSV52238853; called by muse, mutect2, varscan2
- RPE65 | c.1194C>T p.D398= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as rs139640666, COSV52019104; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC22A1 | c.1380C>T p.F460= | Silent (SNP) | VAF 119/273 reads (44%) | catalogued as rs141274044; called by muse, mutect2, varscan2
- TAS2R1 | c.168T>A p.I56= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV66779613; called by muse, mutect2, varscan2
- ZNF80 | c.582C>T p.C194= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs774294338, COSV57360776, COSV57361810; called by muse, mutect2, varscan2
- EYA4 | c.1757-118G>A | Intron (SNP) | VAF 251/610 reads (41%) | catalogued as rs757084701, COSV100766002, COSV62052455; called by muse, mutect2, varscan2
- TTN | c.34265-5698C>T | Intron (SNP) | VAF 30/140 reads (21%) | catalogued as COSV100635079; called by muse, mutect2, varscan2
- ZNF658B | n.2283C>T | RNA (SNP) | VAF 44/216 reads (20%) | called by mutect2, varscan2
